Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q0, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q0-01A (Primary Tumor).

[page 1 of 3]
lw 8/31/11

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

year old female with right thyroid nodule status post FNA with suspicious cells.

Specimens Submitted:

- 1: Delphian node and pretracheal tissue (fs)
- 2: Right thyroid lobe and isthmus (fs)

DIAGNOSIS:

1. Delphian node and pretracheal tissue (fs):
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 4

2. Right thyroid lobe and isthmus (fs):

Tumor Type:
Papillary carcinoma, classical type with oncocyctic features

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Other Tumor Features:
Necrotic and/or reactive changes

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 2.8 cm.

Tumor Encapsulation:
Completely surrounded

Capsular Invasion:
No definite capsular invasion is noted

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

lw
8/31/11

[page 2 of 3]
Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not identified

Non-Neoplastic Thyroid:
Exhibits chronic lymphocytic thyroiditis
Mild

Parathyroid Glands:
Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh, labeled "Delphian node and pretracheal tissue". It consists of yellow fatty tissue measuring 2 x 0.7 x 0.3 cm. No definite lymph nodes are identified. The specimen is submitted entirely for frozen section.

Summary of Sections:
FSC- frozen section control

2.) The specimen is received fresh, labeled "Right thyroid lobe and isthmus". It consists of an unoriented and previously incised thyroid lobe measuring 5 x 3.3 x 2.3 cm and weighing 20.09 g. The incision opens into a solid, well-circumscribed, oval brown mass measuring 2.8 x 2.6 x 1.5 cm. The lobe is inked black. The remaining thyroid parenchyma is tan. A representative section of the capsule to normal thyroid is submitted for frozen section. The remaining nodule to capsule is entirely submitted. TPS is submitted. Approximately 90% of the specimen is submitted.

Summary of sections:
FSC - frozen section control
N - nodule and nodule to capsule, submitted entirely
RS - representative sections of remaining thyroid

Summary of Sections:

Part 1: Delphian node and pretracheal tissue (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Right thyroid lobe and isthmus (fs)

Block	Sect. Site	PCs
1	FSC	1
10	N	10

[page 3 of 3]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Delphian node and pretracheal tissue (fs): Fatty lymph node, technically difficult to cut. No definite evidence of malignancy.
Permanent diagnosis: Same
2. Frozen section diagnosis: Right thyroid lobe and isthmus (fs): Hurthle cell neoplasm, on representative section. (.
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file 0f32f714-246d-4247-bd82-f9d87c7dcb27 (TCGA-DJ-A2Q0.7A818447-E2BC-4206-BF8E-6BF323630171.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).